Somatic mutation profile of tumor specimen ALCH-B2VH-TTP1-A (aliquot ALCH-B2VH-TTP1-A-1-0-D-A78Q-36) from ALCHEMIST case ALCH-B2VH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 70.1 years (25,605 days).
Specimen ALCH-B2VH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b05afb6-8f39-47d1-aa85-78af3f9726e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2VH-NB1-A (Blood Derived Normal), aliquot ALCH-B2VH-NB1-A-3-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f9d9d65-fc16-41d2-bc69-847330d9e388

The open-access MAF lists 40 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 5, Frame Shift Del 2, Nonsense Mutation 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPG | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1163750955; called by muse, mutect2, varscan2
- ANO1 | c.453C>G p.H151Q | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as COSV60281213; called by muse, mutect2, varscan2
- E2F4 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1417838164, COSV62605874; called by muse, mutect2
- F7 | c.751G>A p.A251T | Missense Mutation (SNP) | VAF 84/238 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1269916662, CM010251, CM099563, COSV60644845; called by muse, mutect2, varscan2
- HCLS1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770634522, COSV100100281; called by muse, mutect2, varscan2
- JMJD1C | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336559705, COSV67861404; called by muse, mutect2, varscan2
- MIP | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs139963297, COSV57788064; ClinVar: likely benign; called by muse, mutect2, varscan2
- RGMA | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs774790049, COSV61233152; called by muse, mutect2, varscan2
- SYT16 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 71/152 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs200172983, COSV70857209; called by muse, mutect2, varscan2
- TRIOBP | c.6391C>T p.R2131W (on ENST00000644935 / NM_001039141.3; = p.R418W on NM_007032.5) | Missense Mutation (SNP) | VAF 159/337 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1392355354; called by muse, mutect2, varscan2
- ZNF254 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 143/412 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV100741756; called by muse, mutect2, varscan2
- ZNF398 | c.1675C>T p.R559C (on ENST00000475153 / NM_170686.3; = p.R388C on NM_020781.4) | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140277862; called by muse, mutect2, varscan2
- CLYBL | c.1016A>C p.E339A | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HPS5 | c.2462T>C p.V821A (on ENST00000349215 / NM_181507.2; = p.V707A on NM_007216.4) | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IL23R | c.500C>G p.T167R | Missense Mutation (SNP) | VAF 143/307 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- OR5AP2 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF14 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 254/701 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- RELN | c.1234T>C p.S412P | Missense Mutation (SNP) | VAF 197/450 reads (44%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SLC25A11 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLIT3 | c.1243del p.L415Cfs*20 | Frame Shift Del (DEL) | VAF 38/117 reads (32%) | called by mutect2, pindel, varscan2
- SMU1 | c.1153A>T p.N385Y | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TAF1L | c.3446_3470del p.R1149Qfs*16 | Frame Shift Del (DEL) | VAF 40/136 reads (29%) | called by mutect2, pindel, varscan2
- TLE6 | c.715A>G p.R239G (on ENST00000246112 / NM_001143986.2; = p.R116G on NM_024760.3) | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WAC | c.863T>G p.L288* | Nonsense Mutation (SNP) | VAF 66/136 reads (49%) | called by muse, mutect2, varscan2
- ZNF12 | c.1769C>G p.S590* (on ENST00000405858 / NM_016265.4; = p.S552* on NM_006956.3) | Nonsense Mutation (SNP) | VAF 58/115 reads (50%) | called by muse, mutect2, varscan2
- AGAP5 | c.2055C>T p.C685= | Silent (SNP) | VAF 18/145 reads (12%) | catalogued as rs3998255; called by mutect2, varscan2
- ITIH2 | c.834C>T p.D278= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs763511313; called by muse, mutect2, varscan2
- LRRC14 | c.618C>T p.P206= | Silent (SNP) | VAF 112/250 reads (45%) | called by muse, mutect2, varscan2
- NDRG4 | c.756G>A p.P252= (on ENST00000570248 / NM_001378344.1; = p.P284= on NM_020465.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 112/298 reads (38%) | catalogued as rs200438297; called by muse, mutect2, varscan2
- P2RY13 | c.561A>T p.T187= | Silent (SNP) | VAF 140/305 reads (46%) | called by muse, mutect2, varscan2
- PLG | c.567T>C p.S189= | Silent (SNP) | VAF 83/204 reads (41%) | called by muse, mutect2, varscan2
- SLC30A3 | c.621C>T p.H207= | Silent (SNP) | VAF 140/308 reads (45%) | catalogued as rs368197900; called by muse, mutect2, varscan2
- ZNF827 | c.474G>A p.P158= | Silent (SNP) | VAF 55/230 reads (24%) | catalogued as rs765128822; called by muse, mutect2, varscan2
- BANP | c.1345-211G>C | Intron (SNP) | VAF 129/255 reads (51%) | called by muse, mutect2, varscan2
- CEP170 | c.1273-72A>G | Intron (SNP) | VAF 112/255 reads (44%) | catalogued as rs1182932507; called by muse, mutect2, varscan2
- EFHB | chr3:19936187 C>T | 5'Flank (SNP) | VAF 45/100 reads (45%) | catalogued as rs1469886052; called by muse, mutect2, varscan2
- EPS15 | c.561+2509A>G | Intron (SNP) | VAF 10/208 reads (5%) | catalogued as rs903125548; called by muse, mutect2
- IMPA2 | c.490+3271G>A | Intron (SNP) | VAF 4/29 reads (14%) | catalogued as rs565695226; called by mutect2, varscan2
- RPLP0P2 | n.1122G>A | RNA (SNP) | VAF 102/283 reads (36%) | called by muse, mutect2, varscan2
- SPG7 | c.377-326A>C | Intron (SNP) | VAF 49/123 reads (40%) | called by muse, mutect2, varscan2
